CMI case MBCProject_0814 — CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/d3a97d7f-4dc4-4898-88fa-c4b160d03182

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Biospecimens (3 samples)
- Sample MBCProject_0814_SALIVA: Sample type: DNA; Tissue type: Normal; Specimen type: Saliva; Biospecimen anatomic site: Other.
- Samples MBCProject_0814_T1_RNA, MBCProject_0814_T1_WES (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Axilla; Preservation method: FFPE.
